Gene-level copy-number profile of tumor specimen TCGA-DK-A6B5-01A from TCGA case TCGA-DK-A6B5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 45.0 years (16,453 days).
Specimen TCGA-DK-A6B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e1a681e8-460f-4ef0-9fda-bae70a9f627d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A6B5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c2a9b3be-a9bc-4a7b-ada3-503e4be51af8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 24,760; copy number 2: 30,634; copy number 3: 3,872; copy number 4: 115; copy number 5: 123; copy number 6: 178; copy number 7: 3; copy number 16: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A6B5-01A-11D-A31K-01): tumor purity 0.76, ploidy 1.68, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:77,915,870–77,918,011, 1 gene: LINC01851.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr4:98,025,390–98,658,611, 7 genes (within-gene range 0–1): RPL5P12, DUTP8, AC019077.1, RAP1GDS1, AC058823.1, TSPAN5, AC108159.1.
- chr4:150,078,445–150,257,438, 2 genes (within-gene range 0–1): DCLK2, RNU7-194P.
- chr4:150,422,645–150,423,642, 1 gene: AC092612.1.
- chr5:131,155,383–131,224,468, 2 genes: HINT1, LYRM7.
- chr5:131,261,321–131,261,607, 1 gene: AC004777.1.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr9:21,453,802–22,455,740, 24 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:23,291,544–23,682,662, 5 genes: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr14:44,763,153–44,782,829, 1 gene: LINC02302.
- chr14:67,819,779–68,730,218, 5 genes (within-gene range 0–1): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 350 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,519,741–11,557,665, 90 genes, copy number 6 (broad region; genes not listed).
- chr3:11,607,184–11,612,197, 2 genes, copy number 6: AC022001.2, AC022001.3.
- chr3:18,445,024–18,920,401, 1 gene, copy number 6 (within-gene range 3–6): SATB1-AS1.
- chr3:19,148,510–19,702,795, 3 genes, copy number 7: KCNH8, MIR4791, AC061958.1.
- chr3:20,040,446–22,373,321, 12 genes, copy number 5–6 (within-gene range 1–6): KAT2B, MIR3135A, SGO1, SGO1-AS1, RNU6-822P, AC116096.1, RNU6-815P, AC099753.1, VENTXP7, ZNF385D, ZNF385D-AS1, ZNF385D-AS2.
- chr5:50,396,192–50,443,248, 1 gene, copy number 5: EMB.
- chr6:85,557,978–86,436,138, 17 genes, copy number 5 (within-gene range 2–5): AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P.
- chr6:106,271,634–108,261,246, 43 genes, copy number 5 (within-gene range 1–5): U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3.
- chr7:5,306,790–5,563,902, 12 genes, copy number 16 (within-gene range 2–16): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1.
- chr7:5,823,160–6,161,564, 15 genes, copy number 5 (within-gene range 5–6): ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42.
- chr17:28,744,005–29,567,037, 41 genes, copy number 16: TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15.
- chr17:29,566,052–29,594,054, 3 genes, copy number 16: TP53I13, AC104564.3, GIT1.
- chr17:29,591,703–29,592,241, 1 gene, copy number 16: AC104564.4.
- chr20:22,343,693–23,689,040, 45 genes, copy number 6: AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4.
- chr21:22,205,192–25,772,460, 50 genes, copy number 5–6: RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.
- chr21:26,158,091–27,143,949, 14 genes, copy number 5: AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2.

Autosomal genes at a single copy (total copy number 1): 22,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
